Somatic mutation profile of tumor specimen MBCProject_2071_T1_WES (aliquot MBCProject_2071_T1_WES_1) from CMI case MBCProject_2071, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 39.6 years (14,450 days).
Specimen MBCProject_2071_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef7eec49-7327-450e-ae80-b8066f160a73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2071_SALIVA (Saliva), aliquot MBCProject_2071_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f42cafd-0d84-49f6-876e-8ef0a01e89b2

The open-access MAF lists 191 somatic variants for this specimen: 121 protein-altering or splice-affecting, 46 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 46, Intron 14, Nonsense Mutation 13, 3'UTR 5, Frame Shift Ins 3, Frame Shift Del 2, 3'Flank 2, Splice Region 2, Splice Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 20/210 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AADACL3 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as rs78526061; called by muse, mutect2, varscan2
- AHCTF1 | c.6727G>C p.E2243Q (on ENST00000366508; = p.E2217Q on NM_015446.5) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1212330737; called by muse, mutect2
- APC2 | c.5132C>T p.S1711L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs140312684, COSV52016645; called by muse, varscan2
- ASTN1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.217); catalogued as rs747665952; called by muse, mutect2, varscan2
- BAIAP3 | c.3103G>A p.A1035T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs748030455; called by muse, mutect2, varscan2
- C10orf71 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs199973893; called by mutect2, varscan2
- C11orf98 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.773); catalogued as rs773542054; called by muse, mutect2, varscan2
- CCDC141 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as COSV55370988, COSV55379476; called by muse, mutect2, varscan2
- CCER1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs772988715; called by muse, mutect2, varscan2
- CLRN2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs374428888; called by muse, mutect2, varscan2
- DAB2 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as rs1189582790; called by muse, mutect2, varscan2
- DCX | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as CM131047, COSV100576530; called by muse, mutect2, varscan2
- DNAJB13 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV60268842; called by muse, mutect2, varscan2
- DNMBP | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs527395031; called by muse, mutect2, varscan2
- EYS | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60980846, COSV60989017; called by muse, mutect2, varscan2
- FAT2 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as COSV55812599; called by muse, mutect2, varscan2
- GLCCI1 | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs754232265; called by muse, varscan2
- IRF5 | c.1055C>G p.S352* | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | catalogued as COSV50857786; called by muse, mutect2, varscan2
- KCNA6 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99768200; called by muse, mutect2, varscan2
- KRT23 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544856938, COSV52928917; called by muse, mutect2, varscan2
- KRT33A | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.246); catalogued as rs1272710110, COSV99144892; called by muse, mutect2
- MAGT1 | c.185G>A p.R62H (on ENST00000618282 / NM_001367916.1; = p.R94H on NM_032121.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs1557217716, COSV104419140; called by muse, mutect2, varscan2
- MCM5 | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as rs754396597; called by muse, mutect2, varscan2
- MKI67 | c.4962G>C p.Q1654H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs762529280; called by muse, varscan2
- MPIG6B | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1374385431; called by muse, mutect2, varscan2
- MPST | c.332C>T p.P111L (on ENST00000341116 / NM_001369904.2; = p.P131L on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479809595, COSV62017875; called by muse, mutect2, varscan2
- MTIF3 | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101137580; called by muse, mutect2, varscan2
- OR5H15 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1046142993, COSV62947886; called by muse, mutect2, varscan2
- PIK3R3 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53110478, COSV99422216; called by muse, varscan2
- PPP2R5A | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as rs1440333259; called by muse, mutect2, varscan2
- PPP6C | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV65209634; called by muse, mutect2, varscan2
- PPT2 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52998880; called by muse, mutect2
- PRDM16 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54593919; called by muse, mutect2, varscan2
- PRDX1 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV99423652; called by muse, mutect2, varscan2
- PROSER3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV56554465; called by muse, mutect2, varscan2
- RAD51AP2 | c.246del p.F82Lfs*21 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as COSV67587537; called by mutect2, pindel, varscan2
- RADIL | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs746219713, COSV68204173; called by muse, mutect2, varscan2
- RIC8A | c.1102G>A p.E368K (on ENST00000526104 / NM_001286134.1; = p.E374K on NM_021932.5) | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57342301; called by muse, mutect2, varscan2
- RIC8A | c.1309G>A p.E437K (on ENST00000526104 / NM_001286134.1; = p.E443K on NM_021932.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV100291385; called by muse, mutect2, varscan2
- RPL23 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV55560131; called by muse, mutect2
- RYR2 | c.6320C>T p.T2107M | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs370331492, COSV63669380; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1296754841, COSV73306174; called by muse, mutect2, varscan2
- SELENOV | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as rs1218174552; called by muse, mutect2
- SLC24A5 | c.489G>A p.T163= | Splice Region (SNP) | VAF 4/33 reads (12%) | catalogued as rs572070402, COSV58317496; called by mutect2, varscan2
- SORL1 | c.4124G>A p.R1375Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs138963614; called by muse, mutect2, varscan2
- SOX17 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.011); catalogued as rs904970570, COSV52025024, COSV52027418; called by muse, mutect2, varscan2
- SPINT2 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1386633374, COSV56647908; called by muse, mutect2, varscan2
- TAF1 | c.3961C>G p.L1321V (on ENST00000373790 / NM_138923.4; = p.L1342V on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV52118283; called by muse, mutect2, varscan2
- TGFBI | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs188322933; called by muse, mutect2, varscan2
- TP53 | c.243_247dup p.A83Dfs*42 | Frame Shift Ins (INS) | VAF 27/106 reads (25%) | catalogued as COSV53064565; called by mutect2, pindel, varscan2
- UTRN | c.7640C>T p.S2547F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100838009; called by muse, mutect2
- ZBTB16 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs145635689, COSV100252307; called by muse, mutect2, varscan2
- ZNF100 | c.1519C>G p.H507D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770037782, COSV59748340; called by muse, mutect2, varscan2
- ZNF185 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.314); catalogued as rs376885854, COSV59277411; called by muse, mutect2, varscan2
- ACADS | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- AKAP8 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AL645922.1 | c.2145_2149del p.T716Afs*33 | Frame Shift Del (DEL) | VAF 39/284 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD60 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA4 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATG13 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, varscan2
- ATG16L2 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- ATP5F1C | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ATP8B2 | c.650C>T p.S217L (on ENST00000672630; = p.S184L on NM_001005855.2) | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- BICD1 | c.1750G>C p.E584Q | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- BICD1 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- BIRC6 | c.1346C>G p.S449* | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- C1orf194 | c.115C>T p.Q39* (on ENST00000369948 / NM_001245025.3; = p.Q27* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CD83 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- CDCA3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CDS2 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CNOT9 | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, varscan2
- CR1 | c.3245G>C p.R1082T | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- DAAM2 | c.3064G>C p.E1022Q (on ENST00000274867 / NM_001201427.2; = p.E1021Q on NM_015345.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, varscan2
- DNAAF2 | c.2117C>G p.T706S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH10 | c.8845dup p.S2949Ffs*2 (on ENST00000409039; = p.S2888Ffs*2 on NM_207437.3) | Frame Shift Ins (INS) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- DNAJC14 | c.1414C>G p.P472A | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK2 | c.3551A>T p.K1184M | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, varscan2
- EIF2A | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- FAM135A | c.3956C>G p.S1319* (on ENST00000370479 / NM_001351599.1; = p.S1106* on NM_020819.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- FAM193A | c.3400C>T p.Q1134* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- FAM47A | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT2 | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAT2 | c.1758G>A p.M586I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- GMPPB | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- GNL2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); called by mutect2, varscan2
- GPATCH1 | c.1247C>G p.S416C | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, varscan2
- IFT80 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ISYNA1 | c.1667_1668dup p.T557Pfs*24 | Frame Shift Ins (INS) | VAF 18/108 reads (17%) | called by mutect2, pindel
- KDM7A | c.1613G>C p.R538T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, varscan2
- KLHL4 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LYL1 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2
- MAP3K7CL | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- MAST3 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- MCMBP | c.1689T>G p.Y563* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- NPHP3 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PIGZ | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PPIP5K1 | c.3428C>G p.P1143R (on ENST00000396923; = p.P1118R on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PRXL2B | c.692C>A p.S231Y (on ENST00000444521; = p.S183Y on NM_152371.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SH2D2A | c.309-1G>A p.X103_splice | Splice Site (SNP) | VAF 34/235 reads (14%) | called by muse, mutect2, varscan2
- SHISA6 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 84/271 reads (31%) | called by muse, mutect2, varscan2
- STIL | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- STT3B | c.1954C>G p.L652V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAS1R3 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- TAS2R31 | c.447G>C p.M149I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, varscan2
- TBX5 | c.1137G>A p.M379I | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TEF | c.603C>G p.F201L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TF | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); called by muse, varscan2
- TFAM | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TFE3 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.602); called by muse, mutect2
- TOPBP1 | c.3440A>T p.D1147V | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TTC30A | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP3 | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | called by muse, varscan2
- UBE3A | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VPS72 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, varscan2
- WASHC2C | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- WDR46 | c.1608G>C p.Q536H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- WDR62 | c.1548G>A p.L516= | Splice Region (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- YTHDF3 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ZNFX1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- ABCC4 | c.1581G>A p.V527= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs1224013428; called by muse, mutect2
- BCAS4 | c.561C>A p.S187= | Silent (SNP) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- CADM4 | c.993G>A p.A331= | Silent (SNP) | VAF 46/258 reads (18%) | catalogued as rs748349226; called by muse, mutect2, varscan2
- CATSPERE | c.357C>A p.I119= | Silent (SNP) | VAF 11/84 reads (13%) | called by mutect2, varscan2
- CAV3 | c.261C>T p.L87= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- CFAP47 | c.4149C>G p.L1383= | Silent (SNP) | VAF 15/126 reads (12%) | called by muse, mutect2, varscan2
- CST3 | c.216G>A p.A72= | Silent (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3291G>A p.Q1097= (on ENST00000400246; = p.Q1166= on NM_014662.5) | Silent (SNP) | VAF 40/215 reads (19%) | called by muse, mutect2, varscan2
- DNMT1 | c.4476C>T p.F1492= | Silent (SNP) | VAF 29/160 reads (18%) | called by muse, mutect2, varscan2
- EPPK1 | c.1176G>T p.L392= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs782290933; called by muse, mutect2, varscan2
- ERBB3 | c.3744C>T p.I1248= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs1467142802; called by muse, mutect2, varscan2
- FAM50B | c.456C>T p.F152= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs745966134; called by muse, mutect2, varscan2
- FUT4 | c.138G>A p.A46= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as COSV100708161; called by muse, mutect2, varscan2
- GCN1 | c.6033G>A p.R2011= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1411389109; called by muse, mutect2, varscan2
- GLUL | c.1056A>G p.T352= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as rs201149359; called by muse, mutect2, varscan2
- GPATCH1 | c.1404C>T p.N468= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs373378112; called by muse, mutect2, varscan2
- GPSM1 | c.1053C>T p.F351= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs997255811; called by muse, mutect2, varscan2
- H2AC8 | c.366G>A p.E122= | Silent (SNP) | VAF 31/218 reads (14%) | catalogued as COSV55126469, COSV55126575; called by muse, mutect2, varscan2
- HOXA10 | c.1146C>T p.I382= | Silent (SNP) | VAF 27/145 reads (19%) | called by muse, mutect2, varscan2
- JUNB | c.879C>T p.I293= | Silent (SNP) | VAF 88/472 reads (19%) | catalogued as rs889966481, COSV56878245, COSV56878450; called by muse, mutect2, varscan2
- KIF19 | c.1032G>A p.K344= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- KRT72 | c.30C>T p.R10= | Silent (SNP) | VAF 88/339 reads (26%) | catalogued as rs1222422528; called by muse, mutect2, varscan2
- MOV10 | c.1701C>T p.L567= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV100659566; called by muse, mutect2, varscan2
- NID1 | c.2178C>T p.I726= | Silent (SNP) | VAF 44/239 reads (18%) | catalogued as COSV51628171; called by muse, mutect2, varscan2
- NLRX1 | c.960C>T p.L320= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- NR2F2 | c.516C>T p.L172= | Silent (SNP) | VAF 50/218 reads (23%) | catalogued as COSV67684315; called by muse, mutect2, varscan2
- ODF3 | c.684G>C p.L228= | Silent (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- PGAP6 | c.735G>A p.P245= | Silent (SNP) | VAF 49/197 reads (25%) | catalogued as rs778017624; called by muse, mutect2, varscan2
- PNPLA6 | c.3999G>A p.S1333= (on ENST00000414982 / NM_001166111.2; = p.S1285= on NM_006702.5) | Silent (SNP) | VAF 35/206 reads (17%) | catalogued as rs141360025; called by muse, mutect2, varscan2
- PPP1R16B | c.198C>T p.F66= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV55375283; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1125G>A p.E375= (on ENST00000352766; = p.E296= on NM_181334.5) | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- PSMB7 | c.606C>T p.I202= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs549166919, COSV99412976; called by muse, varscan2
- PTPRJ | c.1788G>C p.L596= | Silent (SNP) | VAF 20/146 reads (14%) | called by muse, mutect2, varscan2
- PZP | c.1185C>T p.T395= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, varscan2
- RBM23 | c.927C>T p.I309= (on ENST00000359890 / NM_001077351.2; = p.I293= on NM_018107.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2, varscan2
- RCE1 | c.744C>T p.F248= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as rs1323140264; called by muse, mutect2, varscan2
- RPS7 | c.207G>A p.L69= | Silent (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- SBNO2 | c.3909C>T p.L1303= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- SPAG9 | c.2097G>A p.K699= (on ENST00000262013 / NM_001130528.3; = p.K685= on NM_003971.6) | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, varscan2
- TTC3 | c.5757C>T p.P1919= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs759668092, COSV61291192; called by muse, mutect2, varscan2
- USP18 | c.768C>G p.L256= | Silent (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- WDR46 | c.681G>A p.K227= | Silent (SNP) | VAF 51/330 reads (15%) | catalogued as COSV65842248; called by muse, mutect2, varscan2
- WNT6 | c.522C>T p.D174= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs748196814, CM152385, COSV99293252; called by muse, varscan2
- YTHDF3 | c.1392C>T p.L464= | Silent (SNP) | VAF 29/184 reads (16%) | called by muse, mutect2, varscan2
- ZAR1 | c.1011C>T p.I337= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs566122509; called by muse, varscan2
- ZNF550 | c.111C>T p.Y37= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as rs767784480, COSV57304509; called by muse, mutect2, varscan2
- ARFGAP3 | chr22:42858434 G>A | 5'Flank (SNP) | VAF 14/225 reads (6%) | catalogued as rs1251867768; called by muse, mutect2
- ARHGDIA | c.*241G>A | 3'UTR (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- C15orf40 | c.366+132T>C | Intron (SNP) | VAF 9/37 reads (24%) | catalogued as rs1210782920, COSV58449491; called by muse, varscan2
- C19orf12 | chr19:29699429 A>G | 3'Flank (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CLCN5 | c.17-33352C>T | Intron (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- CRIM1 | c.2429-5388G>A | Intron (SNP) | VAF 24/137 reads (18%) | catalogued as COSV54867837; called by muse, mutect2, varscan2
- CTSL3P | n.335G>A | RNA (SNP) | VAF 8/60 reads (13%) | catalogued as rs763843296; called by mutect2, varscan2
- ENTPD5 | chr14:73961428 C>G | 3'Flank (SNP) | VAF 31/187 reads (17%) | called by muse, mutect2, varscan2
- FAM53C | c.136+19T>G | Intron (SNP) | VAF 7/64 reads (11%) | catalogued as rs1390623498; called by muse, varscan2
- FGF22 | c.214+1035C>T | Intron (SNP) | VAF 22/127 reads (17%) | catalogued as rs959900681; called by muse, mutect2, varscan2
- HOXB3 | c.-159+814C>A | Intron (SNP) | VAF 150/772 reads (19%) | catalogued as COSV61145667; called by muse, mutect2, varscan2
- ITGAX | c.*2C>A | 3'UTR (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- KHDC4 | c.682-190C>T | Intron (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- OLFM3 | c.653-6941G>A | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- PIN1 | c.*197G>C | 3'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- PPP1CC | c.*18C>T | 3'UTR (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- PTMA | c.46-14C>G | Intron (SNP) | VAF 19/93 reads (20%) | called by muse, mutect2, varscan2
- PTMA | c.*480C>G | 3'UTR (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- SLC4A8 | c.-112+11724C>T | Intron (SNP) | VAF 13/91 reads (14%) | catalogued as rs960192295; called by muse, mutect2, varscan2
- SLC4A8 | c.1102-13C>G | Intron (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- SYT8 | c.400-70C>T | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TMEM45A | c.-4+26638G>T | Intron (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- UHRF1 | c.-10-1282C>T | Intron (SNP) | VAF 47/206 reads (23%) | catalogued as rs1387710738; called by muse, mutect2, varscan2
- ZNF135 | c.-47C>G | 5'UTR (SNP) | VAF 34/102 reads (33%) | catalogued as rs944986303; called by muse, mutect2, varscan2
